Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92V, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92V-01A (Primary Tumor).

[page 1 of 3]
Patient Name

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: GLAND AND THYMOMA
2. Lymph node: Inferior cervical lymph node

DIAGNOSIS

1. Thymus, thymectomy:
- a. Thymoma, WHO type AB, with (see Comment):
- i. Maximum tumor dimension: 5.0 cm
- ii. Microscopic transcapsular invasion present (Masaoka-Koga stage IIA)
- b. Non-tumor involved thymic tissue with involutional changes
2. Lymph node, resection (inferior cervical):
- Two lymph nodes, negative for malignancy (0/2)

COMMENT

1. Sections of the thymic resection show a lobulated tumor demonstrating multiple internal fibrous septations and a biphasic pattern consisting of areas of bland spindled cells, interspersed with areas composed predominantly of small lymphocytes admixed with bland epithelioid cells. The tumor appears completely encapsulated. There are several foci of microscopic transcapsular invasion with extension of tumour cells into surrounding fat. Microscopically, the tumor capsule is present less than 1 mm from multiple painted surfaces of the specimen. However, as noted above, the tumor appears encapsulated, and these surfaces likely do not represent true surgical resection margins; the tumor with its capsule appears to have been completely excised in the sections examined.

By immunohistochemistry, the tumor epithelial cells show strong positive staining for pankeratin (AE1/AE3), CK5 and p63, and are negative for CD5. Many of the background lymphocytes stain positive for TdT, CD3, CD5 and CD1a. Overall, the features are of a thymoma showing morphologic features of both medullary and cortical differentiation, consistent with

ICD O-3
Thymoma, type AB
malignant 8582/3
Date: Thymus C379
J 1/2/14

[page 2 of 3]
Patient Name:

MRN:

DOB:

Gender:F

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

WHO type AB, Masaoka-Koga stage IIA.

SYNOPTIC DATA

Specimen:	Thymus
Procedure:	Thymectomy
Specimen Integrity:	Intact
Specimen Weight:	106 g
Histologic Type:	Type AB thymoma
Tumor Size:	Greatest dimension: 5.0 cm
Tumor Extension:	Not applicable: .
Margins:	Margins uninvolved by tumor
	Distance of tumor from closest
margin: 1 mm	
Treatment Effect:	Not applicable: .
Lymph-Vascular Invasion:	Not identified: .
Regional Lymph Nodes:	No regional lymph node metastases
	Number of lymph nodes examined: 2
	Number of lymph nodes involved: 0
Immunohistochemical Staining:	Results: Epithelial cells positive
for AE1/3, CK5, P63, negative for CD5	
Pathologic Staging (Modified Masaoka):	Stage IIA: Microscopic transcapsular
invasion	
Implants / Distant Metastasis:	Cannot be assessed .
Additional Pathologic Findings:	Age-appropriate involution changes

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and "thymus: gland and thymoma". It consists of an unoriented piece of fibroadipose soft tissue weighing 106 g and containing a partly cystic, tan, solid, firm, somewhat lobulated mass measuring 5.0 x 4.3 x 3.5 cm. The tumor appears to be encapsulated. The specimen has overall measurements of 12.0 x 6.0 x 3.5 cm. The cystic component is filled with yellow fluid. The largest cyst

Status: complete

Page: 2 of 3

[page 3 of 3]
Department of Pathology

Patient Name.

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

measures 3.1 cm in greatest dimension. The outer aspect of the specimen is painted with silver nitrate. Elongated strips of fibroadipose tissue are attached to the mass. No lymph nodes are grossly seen in the fibroadipose tissue. Multiple tissue pieces are frozen. Representative sections submitted as follows:

1A-1E tumor with capsule

1F fragments of tumor

1G-H adjacent fibroadipose tissue

2. The specimen labeled with the patient's name and "inferior cervical lymph node" consists of a piece of soft tissue measuring 1.7 x 0.6 x 0.4 cm. A single lymph node measuring 0.4 x 0.4 x 0.3 cm is identified. The specimen is serially sectioned and submitted in toto in block 2A.

Status: complete

Page: 3 of 3

Source: NCI Genomic Data Commons file 7f12059f-ae5c-45a5-b616-ae45cd7e7aa6 (TCGA-XU-A92V.2DE55D76-D73E-4ACA-84DB-619961565D40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).